National Lung Screening Trial (NLST) participant 101543 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 64 years; Gender: male; Race: Black or African-American; Cigarette smoking status at randomisation: current smoker; Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 33): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 210 mA, display field of view 30 cm, reconstruction filter Siemens, other.
- T1 (day 558): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 140 mA, 40 effective mAs, display field of view 27 cm, reconstruction filter Siemens B30 / Siemens B50F.
- T2 (day 922): No screening result: Inadequate Image. Exam quality: non-diagnostic CT (submaximal inspiratory breath-hold, motion artifact); technique as recorded on the form: 120 kVp, 150 mA, 40 effective mAs, display field of view 28 cm, reconstruction filter Siemens B50F / Siemens B30.

Abnormalities recorded by the reading radiologist on the CT screens (4 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 6 mm, longest perpendicular diameter 5 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 58.
- T0 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right lower lobe; longest diameter 21 mm, longest perpendicular diameter 10 mm; margins poorly defined; predominant attenuation ground glass; greatest diameter on CT slice 83.
- T1 abnormality 1: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T1 abnormality 2: Other minor abnormality noted.

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 2,735.
